Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EU, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EU-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:

pelvic mass, core biopsy consistent with myxofibrosarcoma.

Specimens Submitted:

1: Myxofibrosarcoma of right pelvis and iliacus (iliacus and psoas muscle

DIAGNOSIS:

1. Soft tissue mass, right pelvis and iliacus (iliacus and psoas muscle),
excision:

- High grade myxofibrosarcoma (the myxoid component comprises more than 50% of the mass).
- Grossly the tumor was present as three nodules measuring 7.1 x 7 x 4.2 cm; 6.2 x 5.3 x 2.4 cm and 5.7 x 3.5 x 2.1 cm.
- The tumor was surrounded grossly by an intact thin membrane, which represents the surgical margin.
- Tumor cells are negative for MDM2 and CDK4 immunostains.
- Adjacent skeletal muscle and adipose tissue are not involved.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the
They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
--------	---------------	---------

** Continued on next page **

ICD-O-3

Fibromyxosarcoma 8811/3

Site ^{CSE} Retroperitoneum C48.0

^{Path} Pelvis NOS C49.5

QW 9/26/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 2 of 2

MDM2.
CDK4.
IMM RECURT

Gross Description:

1) The Specimen received fresh labelled "Iliacus and psoas muscle" consist of a well circumscribe soft tissue mass along with muscle and adipose tissue separately in the same container. The mass measures 13.5 x 7.1 x 6.2cm. The specimen is received unoriented. The adipose tissue measures 9 x 8.5 x 4.1cm and the muscle tissue measures 8.5 x 5.5 x 3.1cm. The outer surface of the mass is inked black and the mass is cut along the long axis. The cut section reveals 3 well circumscribed nodules measuring 7.1 x 7 x 4.2cm; 6.2 x 5.3 x 2.4cm and 5.7 x 3.5 x 2.1cm respectively. All three tumor nodules are covered by a thin membrane. The cut section of all three nodules is gray-tan and homogenous; only rare areas of hemorrhage and necrosis are identified in all three nodules. A part of all three nodules is submitted for TPS and the specimen is photographed. The adipose tissue and muscle received separately from the mass are serially sectioned and are grossly unremarkable.

Summary of sections

LN - Largest nodule

SLN - Second largest nodule

SN - Smallest nodule

A - Representative sections of adipose tissue

M - Representative sections of muscle

Summary of Sections:

Part 1: Myxofibrosarcoma of right pelvis and iliacus (iliacus and psoas muscle

Block	Sect.	Site	PCs
1	A	2	
4	LN	8	
1	M	2	
3	SLN	6	
3	SN	6	

** End of Report **

Criteria:	hw 9/9/13	Yes	No
Diagnostic Discrepancy			✓
Prior Malignancy History	Adenocarcinoma of uterus	✓	
Distal/Synchronous Primary, N/A			✓

Source: NCI Genomic Data Commons file 88bff0be-16cf-42bc-a33a-4afde8b151d1 (TCGA-DX-A7EU.37AAFE86-9CA5-48A3-8EC6-437C14457B17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).